Gene-level copy-number profile of tumor specimen TCGA-02-0069-01A from TCGA case TCGA-02-0069, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 31.9 years (11,668 days).
Specimen TCGA-02-0069-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.11f765bb-1566-49f1-83fe-08ef3cade69a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0069-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fac0a8b5-eb73-4e23-80a3-2968c8fc49dc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 326; copy number 2: 11,106; copy number 3: 31,275; copy number 4: 9,756; copy number 5: 4,742; copy number 6: 1,775; copy number 8: 40; copy number 9: 662; copy number 10: 47; copy number 11: 85.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0069-01): tumor purity 0.73, ploidy 3.31, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 834 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–62,292,337, 156 genes, copy number 9–11 (broad region; genes not listed).
- chr10:44,712–34,815,325, 589 genes, copy number 8–9 (within-gene range 3–9) (broad region; genes not listed).
- chr18:75,642,494–79,970,822, 89 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 326. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
